Somatic mutation profile of tumor specimen MBCProject_0203_T1D_WES (aliquot MBCProject_0203_T1D_WES_1) from CMI case MBCProject_0203, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.4 years (17,691 days).
Specimen MBCProject_0203_T1D_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 007bd58c-a5ea-480c-b50a-ab4cf3fdf537.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0203_SALIVA (Saliva), aliquot MBCProject_0203_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f610a08f-c0e7-45e8-9cfe-462ec645a989

The open-access MAF lists 167 somatic variants for this specimen: 121 protein-altering or splice-affecting, 20 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 20, Intron 14, Frame Shift Del 5, In Frame Del 5, Splice Site 5, Nonsense Mutation 3, 5'UTR 3, 3'UTR 3, 3'Flank 3, Frame Shift Ins 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.548); catalogued as COSV57658675; called by muse, mutect2, varscan2
- AOC3 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs151291423; called by muse, mutect2, varscan2
- ASTN1 | c.3807C>G p.S1269R | Missense Mutation (SNP) | VAF 153/449 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as COSV100706916; called by muse, mutect2, varscan2
- BCL11A | c.1729G>A p.E577K (on ENST00000335712 / NM_001365609.1; = p.E611K on NM_018014.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.548); catalogued as COSV59634856; called by muse, mutect2, varscan2
- CBY2 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV60118086; called by muse, mutect2, varscan2
- CHERP | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as rs779384365, COSV52226935; called by muse, mutect2, varscan2
- CHST2 | c.1226C>G p.A409G | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs769639046; called by muse, varscan2
- CILP | c.1232T>C p.I411T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs201720248; called by mutect2, varscan2
- DNAI4 | c.1778G>T p.W593L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755382003; called by muse, mutect2, varscan2
- DOC2A | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58751371; called by muse, mutect2, varscan2
- FAM20C | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 89/594 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.018); catalogued as rs1245703345; called by muse, mutect2, varscan2
- GALNT12 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 57/474 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs536814570; called by muse, mutect2, varscan2
- HUWE1 | c.3979G>T p.D1327Y | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53339081; called by muse, mutect2, varscan2
- LINGO4 | c.557C>A p.T186N | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.53); catalogued as COSV100562014; called by muse, varscan2
- MAP4K1 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs770505238; called by muse, mutect2, varscan2
- NRAP | c.2756G>A p.G919D (on ENST00000359988 / NM_001322945.2; = p.G884D on NM_006175.4) | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV63494294; called by muse, mutect2
- OBSCN | c.12256C>T p.R4086W | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs566266501; called by muse, mutect2
- OR14A2 | c.728del p.L243Pfs*9 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | catalogued as COSV100825424; called by mutect2, pindel
- OR7A10 | c.533dup p.C179Lfs*2 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs758596389; called by pindel, varscan2
- PCDHAC1 | c.1511G>A p.S504N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as rs1554205862; called by muse, varscan2
- PGGHG | c.1711G>T p.V571L | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs769675098; called by muse, mutect2, varscan2
- PLEKHG4B | c.3383T>G p.F1128C (on ENST00000283426; = p.F1484C on NM_052909.5) | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV52054960; called by muse, mutect2, varscan2
- POU6F2 | c.1130C>A p.T377K | Missense Mutation (SNP) | VAF 47/378 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs1472321299; called by muse, mutect2, varscan2
- PRKCD | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs143488209; ClinVar: uncertain significance; called by mutect2, varscan2
- PRR30 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1382257449; called by muse, mutect2, varscan2
- SDK2 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66183260; called by muse, mutect2
- SELENOV | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 70/501 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1462075637; called by muse, mutect2, varscan2
- SERPINB11 | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV101236322; called by muse, mutect2, varscan2
- SPG7 | c.1903G>A p.E635K (on ENST00000268704; = p.E642K on NM_003119.4) | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1202120338, COSV51954483; called by muse, mutect2, varscan2
- SRRM4 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.02); catalogued as rs770735386; called by muse, mutect2, varscan2
- TCP10L | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs746268293; called by muse, mutect2, varscan2
- TGFB2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745960678; called by muse, mutect2, varscan2
- TGM2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 122/430 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as rs577909675; called by muse, mutect2, varscan2
- A2ML1 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ABCC12 | c.3715-17_3744del p.X1239_splice | Splice Site (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel
- ANK3 | c.6587C>A p.P2196H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO4 | c.2589C>A p.D863E (on ENST00000392977 / NM_001286615.2; = p.D828E on NM_178826.4) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APPL2 | c.433G>C p.A145P | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ARHGAP42 | c.755G>T p.R252M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ARHGEF11 | c.2779A>T p.T927S | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ATP2B4 | c.148_162delinsCTA p.G50_N53del | In Frame Del (DEL) | VAF 28/112 reads (25%) | called by pindel, varscan2*
- BDNF | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CALCR | c.588G>T p.R196S (on ENST00000649521 / NM_001164737.2; = p.R180S on NM_001742.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDYL | c.158G>C p.S53T | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL16A1 | c.506A>T p.H169L | Missense Mutation (SNP) | VAF 97/365 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CRYBA4 | c.300+2_300+19del p.X100_splice | Splice Site (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- DDX31 | c.2372A>G p.Y791C | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- DDX5 | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2
- DNAH3 | c.4662G>A p.M1554I | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH5 | c.2428A>T p.I810F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DNAJC3 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, varscan2
- DOK5 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- EMC1 | c.1038C>G p.S346R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- EMILIN1 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- EPS8L2 | c.984+2T>C p.X328_splice | Splice Site (SNP) | VAF 29/307 reads (9%) | called by muse, mutect2
- FAM122A | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FBXO41 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FOXJ1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- FSD1 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FUZ | c.371_372insTTT p.L124dup | In Frame Ins (INS) | VAF 41/360 reads (11%) | called by mutect2, pindel, varscan2
- GCM2 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 221/913 reads (24%) | called by muse, mutect2, varscan2
- GH1 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 33/710 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- GRIN1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 88/412 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- GRK2 | c.808A>C p.I270L | Missense Mutation (SNP) | VAF 97/311 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- GZMH | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.083); called by muse, varscan2
- HSF5 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- HTR3A | c.764T>G p.F255C | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IQCF1 | c.171+1_171+6del p.X57_splice | Splice Site (DEL) | VAF 22/76 reads (29%) | called by mutect2, pindel, varscan2
- IQCF5 | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 75/123 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM6B | c.4901del p.F1634Sfs*36 (on ENST00000448097 / NM_001348716.1; = p.F1634Sfs*4 on NM_001080424.2) | Frame Shift Del (DEL) | VAF 69/326 reads (21%) | called by mutect2, pindel, varscan2
- KIAA0895 | c.1028A>G p.N343S (on ENST00000297063 / NM_001100425.2; = p.N292S on NM_015314.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1109 | c.8012A>G p.K2671R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIAA1549L | c.3911C>T p.P1304L (on ENST00000321505; = p.P1601L on NM_012194.3) | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIF1A | c.4459A>T p.S1487C (on ENST00000320389 / NM_001379639.1; = p.S1479C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/377 reads (29%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LINGO4 | c.570C>A p.C190* | Nonsense Mutation (SNP) | VAF 24/151 reads (16%) | called by muse, varscan2
- MALT1 | c.2305A>T p.S769C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- MAOA | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MAOB | c.932A>C p.Y311S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MAP1A | c.7006_7017del p.H2336_C2339del | In Frame Del (DEL) | VAF 41/196 reads (21%) | called by mutect2, pindel, varscan2
- MAPK8IP1 | c.607del p.X203_splice | Splice Site (DEL) | VAF 51/317 reads (16%) | called by mutect2, pindel, varscan2
- MAPKBP1 | c.1337A>G p.D446G (on ENST00000456763 / NM_001128608.2; = p.D440G on NM_014994.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MGRN1 | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MLLT6 | c.2975_3013del p.P992_L1004del | In Frame Del (DEL) | VAF 30/156 reads (19%) | called by mutect2, pindel
- MRPL17 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MUC16 | c.34895C>A p.T11632N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.3359_3376del p.I1120_T1125del | In Frame Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- MYH7 | c.1074C>A p.H358Q | Missense Mutation (SNP) | VAF 74/397 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- MYT1L | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- OXCT1 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- OXCT1 | c.484G>T p.G162W | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITPNM2 | c.1208_1210del p.Q403del | In Frame Del (DEL) | VAF 39/259 reads (15%) | called by pindel, varscan2
- PLXNA1 | c.1172A>C p.K391T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PRDM15 | c.871dup p.S291Kfs*54 | Frame Shift Ins (INS) | VAF 17/124 reads (14%) | called by mutect2, pindel, varscan2
- PSG4 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- PTGDR | c.1023A>C p.R341S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.212); called by mutect2, varscan2
- PTPRM | c.4294G>T p.V1432F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PWWP2B | c.172_179del p.D58Pfs*119 | Frame Shift Del (DEL) | VAF 42/292 reads (14%) | called by mutect2, pindel, varscan2
- RABGAP1L | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | called by mutect2, varscan2
- RHBDF2 | c.1526T>C p.I509T | Missense Mutation (SNP) | VAF 52/678 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2
- RLIM | c.1278dup p.E427Rfs*27 | Frame Shift Ins (INS) | VAF 10/66 reads (15%) | called by pindel, varscan2
- RPGR | c.2857A>G p.I953V (on ENST00000339363 / NM_001367249.1; = p.I748V on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINA6 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC19A2 | c.806C>G p.P269R | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.069); called by mutect2, varscan2
- SLC1A4 | c.329T>A p.L110H | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC22A31 | c.237del p.D81Tfs*13 | Frame Shift Del (DEL) | VAF 36/238 reads (15%) | called by pindel, varscan2
- SLC35A1 | c.988T>G p.S330A | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SLCO5A1 | c.1030A>T p.I344F | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SNIP1 | c.1097_1116del p.E366Vfs*6 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by pindel, varscan2
- SPRYD3 | c.731A>C p.D244A | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- STAB2 | c.3518C>T p.T1173I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TAF1L | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- TIGD5 | c.1660C>G p.P554A | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- TPTE | c.1546G>T p.D516Y (on ENST00000618007 / NM_199261.4; = p.D498Y on NM_199259.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- UPP2 | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- WDFY4 | c.4906C>A p.H1636N | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ZAN | c.3725C>G p.A1242G | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ZNF217 | c.1884G>T p.K628N | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF235 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZP2 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZSCAN1 | c.757A>T p.R253W | Missense Mutation (SNP) | VAF 60/414 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- ZSCAN22 | c.206A>T p.H69L | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD12B | c.318G>A p.G106= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.906C>T p.I302= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- CACNA1B | c.1695C>A p.A565= | Silent (SNP) | VAF 103/234 reads (44%) | called by muse, mutect2, varscan2
- CADPS | c.576T>A p.R192= | Silent (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2
- COL20A1 | c.1293G>A p.T431= | Silent (SNP) | VAF 247/578 reads (43%) | catalogued as rs780583500, COSV58918554; called by muse, mutect2, varscan2
- ERCC1 | c.483G>A p.G161= | Silent (SNP) | VAF 92/567 reads (16%) | catalogued as rs371397437; called by muse, mutect2, varscan2
- GAL3ST3 | c.924C>T p.H308= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs1222376422; called by muse, mutect2, varscan2
- INPP4A | c.1336A>C p.R446= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- ITGA9 | c.519C>T p.G173= | Silent (SNP) | VAF 77/256 reads (30%) | called by muse, mutect2, varscan2
- KCND3 | c.1749G>A p.Q583= | Silent (SNP) | VAF 65/298 reads (22%) | called by muse, mutect2, varscan2
- KLHDC8A | c.727C>A p.R243= | Silent (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- KLHDC8A | c.726G>A p.L242= | Silent (SNP) | VAF 26/320 reads (8%) | called by muse, mutect2
- MAP4K4 | c.516T>C p.F172= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs1268907751; called by muse, mutect2, varscan2
- MUC1 | c.3705C>G p.P1235= (on ENST00000611571 / NM_001371720.1; = p.P246= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2
- MUC5B | c.828A>T p.A276= | Silent (SNP) | VAF 52/599 reads (9%) | called by muse, mutect2
- PDE4DIP | c.3024C>T p.H1008= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- PRDM5 | c.1683T>C p.D561= | Silent (SNP) | VAF 24/284 reads (8%) | catalogued as rs1275093218; called by muse, mutect2
- RAB11FIP3 | c.1422G>A p.L474= | Silent (SNP) | VAF 40/389 reads (10%) | catalogued as COSV51933771, COSV99240493; called by muse, mutect2, varscan2
- RASGRP4 | c.645G>C p.R215= | Silent (SNP) | VAF 60/162 reads (37%) | called by muse, mutect2, varscan2
- TRAV6 | c.309C>G p.V103= | Silent (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2
- AC090151.1 | chr8:54701643 A>T | 3'Flank (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- CFTR | c.-34C>T | 5'UTR (SNP) | VAF 74/240 reads (31%) | catalogued as rs756314710, CR118489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRIM1 | c.2429-5437C>T | Intron (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- DAPK1 | c.1626+45G>T | Intron (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- DERL1 | c.-1G>T | 5'UTR (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- DGKD | c.157-2253C>T | Intron (SNP) | VAF 11/81 reads (14%) | catalogued as rs1015956368; called by mutect2, varscan2
- ELP4 | c.1146+31790A>G | Intron (SNP) | VAF 11/113 reads (10%) | catalogued as rs1454859479; called by muse, mutect2
- GPATCH8 | c.*1799A>G | 3'UTR (SNP) | VAF 31/202 reads (15%) | called by muse, mutect2, varscan2
- LTB | c.208+43G>C | Intron (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- MATR3 | c.*1448A>G | 3'UTR (SNP) | VAF 11/80 reads (14%) | catalogued as rs1298787056; called by muse, varscan2
- MEGF6 | c.3353-200G>A | Intron (SNP) | VAF 14/184 reads (8%) | catalogued as rs1332519551; called by muse, mutect2
- MST1L | n.1482C>A | RNA (SNP) | VAF 52/566 reads (9%) | catalogued as rs1409336080; called by muse, varscan2
- NECAP2 | c.489+959C>G | Intron (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- NELL1 | c.1549+54896C>A | Intron (SNP) | VAF 11/99 reads (11%) | catalogued as rs1374824140; called by muse, mutect2, varscan2
- PCSK5 | c.2626+3607G>T | Intron (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- PLEKHM1P1 | n.1581G>T | RNA (SNP) | VAF 74/1254 reads (6%) | called by muse, mutect2
- POLR2H | c.-53C>G | 5'UTR (SNP) | VAF 168/570 reads (29%) | called by muse, mutect2, varscan2
- POTEG | c.811-1030A>G | Intron (SNP) | VAF 48/529 reads (9%) | called by muse, varscan2
- PTPN18 | c.414+2592A>G | Intron (SNP) | VAF 8/53 reads (15%) | catalogued as rs1254023457, COSV51558883; called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 36/516 reads (7%) | catalogued as rs910081914; called by muse, mutect2
- SMARCD2 | c.*1C>T | 3'UTR (SNP) | VAF 38/469 reads (8%) | called by muse, mutect2
- SNX29 | c.247+2193T>G | Intron (SNP) | VAF 23/210 reads (11%) | called by muse, varscan2
- STXBP2 | c.88-22_88-19del | Intron (DEL) | VAF 110/307 reads (36%) | called by mutect2, pindel, varscan2
- TK1 | chr17:78187097 A>G | 5'Flank (SNP) | VAF 22/396 reads (6%) | catalogued as rs1216718360; called by muse, mutect2
- TMEM67 | chr8:93819062 A>C | 3'Flank (SNP) | VAF 20/316 reads (6%) | called by muse, mutect2
- ZNF90 | chr19:20121323 T>C | 3'Flank (SNP) | VAF 8/77 reads (10%) | catalogued as rs1555706533; called by mutect2, varscan2
